Somatic mutation profile of tumor specimen TCGA-AA-3994-01A (aliquot TCGA-AA-3994-01A-01W-1073-09) from TCGA case TCGA-AA-3994, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.3 years (25,323 days).
Specimen TCGA-AA-3994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1477013a-81fe-4a35-9c5c-19e0d4bbe2d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3994-10A (Blood Derived Normal), aliquot TCGA-AA-3994-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b4fbeb-7e2d-46ae-b9a2-6a9e777c5f70

The open-access MAF lists 202 somatic variants for this specimen: 148 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 51, Nonsense Mutation 14, Intron 2, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2, Translation Start Site 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 77/199 reads (39%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 123/368 reads (33%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 632/747 reads (85%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 405/549 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs1338467462, COSV59318951; called by muse, mutect2, varscan2
- ACTL7B | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263764064, COSV65926824; called by muse, mutect2, varscan2
- ACVR1B | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 91/245 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs200366489, COSV57777675; called by muse, mutect2, varscan2
- ADNP | c.3096del p.Y1033Mfs*48 | Frame Shift Del (DEL) | VAF 73/265 reads (28%) | catalogued as COSV62424447; called by mutect2, pindel, varscan2
- AHNAK | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs755949381, COSV57216146; called by muse, mutect2, varscan2
- AIRE | c.294C>A p.D98E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52394554; called by muse, mutect2
- ANKRD55 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs772126737, COSV61947301; called by muse, mutect2, varscan2
- ANO4 | c.1367G>A p.W456* (on ENST00000392977 / NM_001286615.2; = p.W421* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 61/160 reads (38%) | catalogued as rs1440572065, COSV54598513; called by muse, mutect2, varscan2
- APBB1IP | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63302759; called by muse, mutect2, varscan2
- APCDD1L | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs761827739, COSV64485444; called by muse, mutect2, varscan2
- ASB15 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 32/498 reads (6%) | catalogued as COSV99306792; called by muse, mutect2
- ASCL4 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV60816762; called by muse, mutect2
- ATP4A | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as rs200663366; called by muse, mutect2, varscan2
- BACE2 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57738858, COSV57740234; called by muse, mutect2, varscan2
- BPIFB1 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as rs952016082, COSV53606432; called by muse, mutect2, varscan2
- BRD8 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs555229577, COSV50151214; called by muse, mutect2, varscan2
- BRS3 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752869358, COSV101036617; called by muse, mutect2
- CADPS | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147087123; called by muse, mutect2
- CAMK2A | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1439139668, COSV62245806; called by muse, mutect2, varscan2
- CCDC180 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368120179; called by muse, mutect2, varscan2
- CCDC28B | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs145792550, COSV52211317; called by muse, mutect2, varscan2
- CDH23 | c.3179G>T p.R1060L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV54937509; called by muse, mutect2
- CDK17 | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV54129946; called by muse, mutect2, varscan2
- CDK2 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57186718, COSV57187472; called by muse, mutect2, varscan2
- CKM | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1252321977, COSV99675593; called by muse, mutect2, varscan2
- CNTNAP2 | c.102A>T p.K34N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV62192026; called by muse, mutect2, varscan2
- COL12A1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59397512; called by muse, mutect2, varscan2
- COL1A2 | c.2452C>A p.L818I | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs767839892, COSV51959626; called by muse, mutect2, varscan2
- CPN1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1214849079, COSV64942366; called by muse, mutect2, varscan2
- CSMD2 | c.3859G>A p.G1287R | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs973556782, COSV53911521; called by muse, mutect2, varscan2
- DCAF4L2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV60476889; called by muse, mutect2, varscan2
- EGR1 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV53519892; called by muse, mutect2, varscan2
- EPB41L3 | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.278); catalogued as rs558098862, COSV59453540, COSV59456315; called by muse, mutect2, varscan2
- EPB41L5 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770943181, COSV55353134; called by muse, mutect2, varscan2
- ESPL1 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs752710244, COSV57759948; called by muse, mutect2, varscan2
- EYS | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 59/158 reads (37%) | catalogued as COSV60984192, COSV60993750; called by muse, mutect2, varscan2
- FAM135A | c.439G>A p.G147S (on ENST00000370479 / NM_001351599.1; = p.G104S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52052823; called by muse, mutect2, varscan2
- FREM1 | c.3544G>T p.A1182S | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1563961605, COSV66524874; called by muse, mutect2, varscan2
- FREM1 | c.3247G>T p.E1083* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV66519006, COSV66524879, COSV66531140; called by muse, mutect2, varscan2
- FSTL1 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV55234171; called by muse, mutect2, varscan2
- FTMT | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs372731129, COSV58420377; called by muse, varscan2
- FYN | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as COSV57615451; called by muse, mutect2, varscan2
- GLUD2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs760835465, COSV60152067; called by muse, mutect2, varscan2
- GPR176 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV54445563; called by muse, mutect2
- GRK5 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.399); catalogued as rs771181138, COSV64866564; called by muse, mutect2, varscan2
- GRM1 | c.3217C>A p.Q1073K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.081); catalogued as COSV99267503; called by muse, mutect2, varscan2
- HEATR6 | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs767625150, COSV51746262; called by muse, mutect2, varscan2
- HLX | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65044944; called by muse, mutect2, varscan2
- HRC | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs1470781154, COSV53256791; called by muse, mutect2, varscan2
- HTT | c.4234C>T p.R1412C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754826573, COSV100751302, COSV61863414; called by muse, mutect2, varscan2
- HUS1B | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57866077; called by muse, varscan2
- IL1RAP | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99299960; called by muse, mutect2
- IL6ST | c.1879T>G p.L627V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV61141506; called by muse, mutect2, varscan2
- INHBA | c.1048T>C p.C350R | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54222098; called by muse, mutect2, varscan2
- IPO8 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 57/188 reads (30%) | catalogued as COSV99805501; called by muse, mutect2, varscan2
- IQCJ | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV67333337; called by muse, mutect2, varscan2
- ITPR1 | c.4559A>G p.Y1520C (on ENST00000354582; = p.Y1505C on NM_002222.7) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV56985162; called by muse, mutect2, varscan2
- JAKMIP3 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371348426; called by muse, mutect2, varscan2
- KALRN | c.5592G>C p.Q1864H (on ENST00000360013 / NM_001024660.4; = p.Q167H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV52258099; called by muse, mutect2, varscan2
- KALRN | c.7903G>A p.G2635R (on ENST00000360013 / NM_001024660.4; = p.G938R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751599377, COSV52258120; called by muse, mutect2, varscan2
- KCNJ12 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373382377, COSV59168414; called by muse, mutect2, varscan2
- KLHDC8B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs11558200, COSV100234262; called by muse, mutect2
- KLHL6 | c.1717A>C p.I573L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV58066934; called by muse, mutect2, varscan2
- LEF1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54468252; called by muse, mutect2, varscan2
- LRP1B | c.10315G>T p.D3439Y | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV67230034; called by muse, mutect2, varscan2
- LVRN | c.1574C>A p.A525E | Missense Mutation (SNP) | VAF 116/220 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63497437; called by muse, mutect2, varscan2
- MAFB | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as COSV64826481; called by muse, mutect2, varscan2
- MAGEE1 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs782669089, COSV63910576; called by muse, mutect2, varscan2
- MDGA2 | c.1004C>A p.T335K (on ENST00000399232 / NM_001113498.2; = p.T37K on NM_182830.4) | Missense Mutation (SNP) | VAF 176/234 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV62080911, COSV62096085; called by muse, mutect2, varscan2
- MOCS1 | c.1538T>G p.L513R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV99226347; called by muse, mutect2, varscan2
- MRGPRX3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs201248611, COSV66934095; called by muse, mutect2, varscan2
- MROH8 | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54120722; called by muse, mutect2, varscan2
- MYLK | c.3548G>T p.C1183F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60612199; called by muse, mutect2, varscan2
- MYO1H | c.1613dup p.N538Kfs*3 | Frame Shift Ins (INS) | VAF 17/47 reads (36%) | catalogued as rs750113937; called by mutect2, varscan2
- MYT1L | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs754747899, COSV67706497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAE1 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 73/167 reads (44%) | catalogued as COSV51976750; called by muse, mutect2, varscan2
- NAT10 | c.2032G>T p.V678F | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV57664283; called by muse, mutect2, varscan2
- NLRP9 | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 124/386 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60464028; called by muse, mutect2, varscan2
- NUDT10 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1485048141, COSV62854257; called by muse, mutect2, varscan2
- OCM | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs745567019, COSV54194553; called by muse, mutect2, varscan2
- OLFM1 | c.1232C>T p.T411M (on ENST00000371793 / NM_001282611.2; = p.T393M on NM_014279.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767622547, COSV53277197, COSV53278980; called by muse, mutect2, varscan2
- OR1C1 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101376252; called by muse, mutect2, varscan2
- OR51M1 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 20/627 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150317; called by muse, mutect2
- OTOL1 | c.293T>A p.F98Y | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV60006995; called by muse, mutect2, varscan2
- PCDH19 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99719897; called by muse, mutect2, varscan2
- PCDHA2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV65367611; called by muse, mutect2, varscan2
- PCDHAC1 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 49/198 reads (25%) | catalogued as COSV53853136; called by muse, mutect2, varscan2
- PCDHGA10 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); catalogued as rs762272586, COSV53963267; called by muse, mutect2, varscan2
- PCDHGB2 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53934338; called by muse, mutect2, varscan2
- PCDHGB3 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53963259; called by muse, mutect2, varscan2
- PGA5 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200405121, COSV56715867; called by muse, mutect2, varscan2
- PLCH2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs777527829, COSV53944214; called by muse, varscan2
- PNMA2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1487114560, COSV72908538; called by muse, mutect2, varscan2
- POGLUT2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65683226; called by muse, mutect2, varscan2
- PPP1R36 | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 65/215 reads (30%) | catalogued as COSV53901642; called by muse, mutect2, varscan2
- PPP2R2C | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs375066274; called by muse, mutect2, varscan2
- PRDM5 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV53359645, COSV53359880, COSV53369535; called by muse, mutect2, varscan2
- RCCD1 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1244067236, COSV62695589; called by muse, mutect2, varscan2
- RET | c.3048G>T p.L1016F | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100394046, COSV60693256; called by muse, mutect2
- ROBO1 | c.3977C>T p.A1326V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs769052045, COSV71395325; called by muse, mutect2, varscan2
- SALL1 | c.2808G>T p.Q936H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV51758732; called by muse, mutect2, varscan2
- SCN2A | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1007052146, COSV51833559; called by muse, mutect2, varscan2
- SIGLEC8 | c.1446G>T p.E482D | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV58474174; called by muse, mutect2, varscan2
- SKIV2L | c.1873T>A p.S625T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV64812169; called by muse, mutect2, varscan2
- SLC12A6 | c.934G>A p.A312T (on ENST00000354181 / NM_001365088.1; = p.A261T on NM_005135.2) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV51626880; called by muse, mutect2
- SMC2 | c.3097G>A p.A1033T | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1353856808, COSV99659360; called by muse, mutect2
- SMC4 | c.817A>G p.R273G | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61005596; called by muse, mutect2, varscan2
- SMIM19 | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60604074; called by muse, mutect2
- SPACA3 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV52191418; called by muse, mutect2, varscan2
- SPEG | c.4073G>A p.R1358Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56670811; called by muse, mutect2, varscan2
- SREBF1 | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55394135; called by muse, mutect2
- SS18 | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.391); catalogued as rs970130538, COSV52261576; called by muse, mutect2, varscan2
- STPG2 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 50/523 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV54787625; called by muse, mutect2
- SYNE1 | c.9959C>T p.T3320M (on ENST00000367255 / NM_182961.4; = p.T3327M on NM_033071.3) | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs548283137, COSV55002913, COSV55134654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.4094G>A p.R1365H (on ENST00000367255 / NM_182961.4; = p.R1372H on NM_033071.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs746133846, COSV55069078; called by mutect2, varscan2
- SYNE1 | c.2704G>T p.A902S (on ENST00000367255 / NM_182961.4; = p.A909S on NM_033071.3) | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.079); catalogued as COSV55002936; called by muse, mutect2, varscan2
- TAB3 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as COSV55839948; called by muse, mutect2
- TAF1L | c.4664T>A p.F1555Y | Missense Mutation (SNP) | VAF 323/522 reads (62%) | SIFT tolerated (0.91); PolyPhen benign (0.158); catalogued as COSV54263096; called by muse, mutect2, varscan2
- TLL1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.984); catalogued as rs537288580, COSV50261081; called by muse, mutect2, varscan2
- TMEM63A | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as rs368334549, COSV100834442; called by muse, mutect2, varscan2
- TMEM74 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755393829, COSV52462669; called by muse, mutect2, varscan2
- TMPRSS3 | c.1306C>G p.R436G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs565348874, CM165509, COSV52303877; called by muse, mutect2, varscan2
- TP53BP2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 93/157 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771266375, COSV59069190; called by muse, mutect2, varscan2
- TRPC4 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 85/304 reads (28%) | catalogued as COSV59002661; called by muse, mutect2, varscan2
- TRPM3 | c.2656G>A p.G886R (on ENST00000357533 / NM_001366142.2; = p.G729R on NM_020952.6) | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1413132526, COSV100677897, COSV62594334; called by muse, mutect2
- TRPS1 | c.3097C>A p.Q1033K (on ENST00000220888 / NM_001330599.2; = p.Q1046K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55244172; called by muse, mutect2, varscan2
- TTN | c.75994C>T p.P25332S (on ENST00000591111; = p.P17908S on NM_003319.4) | Missense Mutation (SNP) | VAF 62/150 reads (41%) | PolyPhen probably damaging (0.998); catalogued as COSV60112025; called by muse, mutect2, varscan2
- TVP23B | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 256/396 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs761798180, COSV57060115; called by muse, mutect2, varscan2
- UNC5C | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71660282; called by muse, mutect2, varscan2
- UNC5D | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV54792203; called by muse, mutect2, varscan2
- UQCRH | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs771218841, COSV61176574; called by muse, mutect2, varscan2
- VAMP8 | c.68T>A p.V23D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55705454; called by muse, mutect2, varscan2
- ZBTB16 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs750494052, COSV60094058; called by muse, mutect2, varscan2
- ZKSCAN5 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs115127995, COSV58743060; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1553T>C p.M518T | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs774145245, COSV58743071; called by muse, mutect2, varscan2
- ZNF436 | c.566C>G p.T189S | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV58358683; called by muse, mutect2, varscan2
- ZNF609 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs370398646, COSV58590620; called by muse, mutect2, varscan2
- ZXDC | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.539); catalogued as rs1030647337, COSV67628788; called by muse, mutect2, varscan2
- COL11A2 | c.4924C>A p.L1642M (on ENST00000341947 / NM_080680.3; = p.L1535M on NM_080679.2) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DNAJB13 | c.687_688dup p.L230Pfs*5 | Frame Shift Ins (INS) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- NPM1 | c.517_524+11del p.X173_splice | Splice Site (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- RNF133 | c.35_37dup p.N12dup | In Frame Ins (INS) | VAF 22/143 reads (15%) | called by mutect2, varscan2
- ACVR1C | c.1281G>A p.S427= | Silent (SNP) | VAF 61/186 reads (33%) | catalogued as rs750781986, COSV54646784, COSV99694880; called by muse, mutect2, varscan2
- ASMTL | c.111G>A p.V37= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV67243903; called by muse, mutect2, varscan2
- CACNA1C | c.4857C>T p.Y1619= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs758486779, COSV59727533; called by muse, mutect2, varscan2
- CAV3 | c.234G>A p.T78= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs148846096; ClinVar: likely benign / benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COL19A1 | c.2121A>G p.K707= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV59575473; called by muse, mutect2, varscan2
- CPPED1 | c.213C>T p.A71= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs776501530, COSV55498325; called by muse, mutect2, varscan2
- CSMD1 | c.1398C>A p.T466= (on ENST00000520002; = p.T465= on NM_033225.6) | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV68171549, COSV68212916; called by muse, mutect2, varscan2
- DCC | c.2757G>A p.S919= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs144874430; called by muse, mutect2, varscan2
- DUSP22 | c.342C>T p.A114= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as rs539737732, COSV60527684; called by muse, mutect2, varscan2
- EBF1 | c.381C>T p.Y127= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV58181152; called by muse, mutect2, varscan2
- EPPK1 | c.6441C>T p.T2147= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs1277205797, COSV73261518; called by muse, mutect2, varscan2
- FAM71C | c.24G>A p.P8= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs562310463, COSV60942533; called by muse, mutect2, varscan2
- FGF13 | c.117G>A p.A39= | Silent (SNP) | VAF 130/200 reads (65%) | catalogued as rs768993513, COSV65436054; called by muse, mutect2, varscan2
- GLI1 | c.1569C>A p.S523= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV57363225; called by muse, mutect2, varscan2
- GPER1 | c.822G>A p.P274= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs369986460; called by muse, mutect2, varscan2
- JMY | c.1407A>G p.S469= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1215472951, COSV101268070; called by muse, mutect2
- KCNB1 | c.504C>T p.C168= | Silent (SNP) | VAF 116/291 reads (40%) | catalogued as rs139960830; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP2 | c.6192C>T p.F2064= | Silent (SNP) | VAF 101/306 reads (33%) | catalogued as COSV55557083; called by muse, mutect2, varscan2
- MDGA1 | c.1275C>T p.P425= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs560720783, COSV51796813; called by muse, mutect2, varscan2
- MN1 | c.3720C>T p.D1240= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV56558967; called by muse, mutect2, varscan2
- MUC16 | c.35029C>A p.R11677= | Silent (SNP) | VAF 184/709 reads (26%) | catalogued as rs747649257, COSV67471715, COSV67478296; called by muse, mutect2, varscan2
- MYH10 | c.1923C>T p.S641= | Silent (SNP) | VAF 153/195 reads (78%) | catalogued as rs1224181552, COSV52601423; called by muse, mutect2, varscan2
- MYOM2 | c.2811C>T p.D937= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs745874438, COSV50720223; called by muse, mutect2, varscan2
- NPR1 | c.2472G>A p.A824= | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as rs372297612; called by muse, mutect2, varscan2
- NPTX2 | c.867C>T p.I289= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs369073829; called by muse, mutect2, varscan2
- NUDT12 | c.1236C>T p.D412= | Silent (SNP) | VAF 5/104 reads (5%) | catalogued as rs901076130, COSV100048267; called by muse, mutect2
- OR5P2 | c.39G>A p.T13= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs111429296; called by muse, mutect2, varscan2
- PCDHGA4 | c.2088C>A p.A696= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99542326; called by muse, mutect2, varscan2
- PCDHGB3 | c.198G>T p.L66= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as COSV99542327; called by muse, mutect2, varscan2
- PCLO | c.4251A>T p.L1417= | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as COSV61639799; called by muse, mutect2, varscan2
- PPARD | c.303G>A p.T101= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs1253117732, COSV61099981; called by muse, mutect2, varscan2
- PPM1K | c.267A>G p.K89= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV55796201; called by muse, mutect2, varscan2
- PPP5C | c.456C>T p.I152= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs775576018, COSV50140549; called by muse, mutect2
- PRAMEF15 | c.495C>T p.Y165= | Silent (SNP) | VAF 366/1572 reads (23%) | called by muse, mutect2, varscan2
- QSER1 | c.3036A>G p.R1012= (on ENST00000399302; = p.R1141= on NM_001076786.3) | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as COSV67900774; called by muse, mutect2, varscan2
- RASGEF1A | c.1116C>T p.S372= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1415560105, COSV65666951; called by muse, mutect2, varscan2
- RTP2 | c.576C>T p.S192= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV64079082; called by muse, mutect2, varscan2
- RYR1 | c.5214G>A p.T1738= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as rs1175081117, COSV62099597; called by muse, mutect2, varscan2
- SAXO2 | c.558T>C p.C186= | Silent (SNP) | VAF 72/208 reads (35%) | catalogued as COSV59754273; called by muse, mutect2, varscan2
- SCN4A | c.2259C>T p.I753= | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as rs1050679031, COSV71127236; called by muse, mutect2, varscan2
- SHMT2 | c.702C>T p.Y234= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs561041442, COSV61074201; called by muse, mutect2, varscan2
- SLAIN2 | c.435G>A p.S145= | Silent (SNP) | VAF 77/197 reads (39%) | catalogued as rs768057039, COSV51907143; called by muse, mutect2, varscan2
- SLC17A5 | c.1431C>T p.F477= | Silent (SNP) | VAF 79/184 reads (43%) | catalogued as rs1382310721, COSV63287579; called by muse, mutect2, varscan2
- SPATA31E1 | c.2010C>T p.D670= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV57792393; called by muse, mutect2, varscan2
- SYNE3 | c.1089G>A p.A363= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1458958235, COSV62080038; called by muse, mutect2, varscan2
- THAP9 | c.1779C>T p.F593= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV56356640; called by muse, mutect2
- TSSK1B | c.567C>A p.G189= | Silent (SNP) | VAF 57/148 reads (39%) | catalogued as COSV66814898, COSV66815349; called by muse, mutect2, varscan2
- TTN | c.24606C>A p.G8202= (on ENST00000591111; = p.G7275= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV60005976; called by muse, mutect2, varscan2
- VAV2 | c.2583C>T p.N861= (on ENST00000371850 / NM_001134398.2; = p.N822= on NM_003371.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs747438873, COSV64082414; called by muse, mutect2, varscan2
- WIPI1 | c.819G>A p.S273= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs747408229, COSV50930245; called by muse, mutect2, varscan2
- ZNF648 | c.1383G>A p.S461= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV60570038; called by muse, mutect2, varscan2
- C3P1 | n.3077G>A | RNA (SNP) | VAF 89/467 reads (19%) | catalogued as rs563514269; called by muse, mutect2, varscan2
- LNX1 | c.380+15665C>T | Intron (SNP) | VAF 12/136 reads (9%) | catalogued as rs761756542, COSV55786660; called by muse, mutect2
- MASP1 | c.1303+5480G>A | Intron (SNP) | VAF 39/97 reads (40%) | catalogued as rs144963945; called by muse, mutect2, varscan2
